MMRF case MMRF_2476 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a5d97b7c-fd30-4792-9e1b-712f70db07a1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 83 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 83.1 years (30,355 days); ISS stage: III; Days to last known disease status: 525 days (1.4 years); Days to last follow up: 525 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 2.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 123 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 5.8 µg/mL; Hemoglobin 6.94 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 341 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.2 mmol/L; Albumin 30 g/L; Total Protein 8.3 g/dL; Glucose 7.26 mmol/L.
- Day 92 (ECOG 1): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Hemoglobin 7.5 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.34 mmol/L.
- Day 181: M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Hemoglobin 6.7 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 307 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 6.6 mmol/L.
- Day 265: M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Hemoglobin 7.5 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.56 mmol/L.
- Day 356: M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 5.38 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 5.78 mmol/L.
- Day 440: M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 7.2 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.12 mmol/L.
- Day 525 (ECOG 0): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 8.35 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 7.43 mmol/L.

Other clinical attributes
- Day -5: Weight: 80 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2476_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2476_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
